Surgical pathology report (de-identified scan), TCGA case TCGA-XF-AAME, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site University of Southern California, specimen TCGA-XF-AAME-01A (Primary Tumor).

[page 1 of 8]
HX SURGICAL PATHOLOGY REPORT

* Final Report *

Document Type:
*Date - Date of Service:
Document Status:
Document Title:
Encounter info:
Contributor System:

* Final Report *

ICD-O-3
Carcinoma, urothelial NOS
8120/3
Site: Bladder NOS
C67.9
JAD 13/26/14

ORDERING PHYSICIAN:
Ordering Physician:

PRE-OPERATIVE DIAGNOSIS:
Bladder cancer

POST-OPERATIVE DIAGNOSIS:
Same as preop

MICROSCOPIC DESCRIPTION:
A-C: See final microscopic-diagnosis.

Per TSS, squamous = 25%.

D: Sections of the bladder show an invasive poorly differentiated urothelial carcinoma (D3,5-9) with focal squamoid features, grade's 3 & 4/4. The carcinoma extends into deep muscle (D3,7) but does not involve perivesical soft tissue and no lymphovascular space invasion is seen. Sections from the right lateral wall and those adjacent to the tumor show areas of urothelial carcinoma in situ (D2,10,11). Random sections from the remainder of the bladder show no evidence of high grade urothelial dysplasia. Resection margins are free of both dysplasia and malignancy.

Sections from the cervix show benign squamous and endocervical mucosa. The endometrium is atrophic. The myometrium contains several small leiomyomas without evidence of cellular atypia or malignancy. Sections of bilateral ovaries and fallopian tubes show physiologic changes without atypical or malignant elements.

E-S: See final microscopic-diagnosis.

Signature Line
Signed by:
ELECTRONIC SIGNATURE

GROSS DESCRIPTION:
A: The specimen is received fresh from the O.R. and labeled "Right distal ureter F/S". It consists of a segment of

Printed by:
Printed on:

Page 1 of 8
(Continued)

[page 2 of 8]
HX SURGICAL PATHOLOGY REPORT

* Final Report *

ureter measuring 0.7 cm in diameter by 0.5 cm in length. The specimen is entirely submitted for frozen section in cassette AFS.

B: The specimen is received fresh from the O.R. and labeled "Left distal ureter F/S". It consists of a segment of ureter measuring 0.4 cm in diameter by 0.3 cm in length. The specimen is entirely submitted for frozen section in cassette BFS.

C: The specimen is received fresh from the O.R. and labeled "Apical urethral margin". It consists of two pieces of tan tissue measuring 1 x 0.4 x 0.3 cm and 2 x 0.2 x 0.2 cm. The specimen is entirely submitted for frozen section in cassette CFS.

D: The specimen is received fresh from the O.R. and labeled "Bladder / uterus". It consists of a radical cystectomy specimen with anterior exenteration measuring overall 12.5 x 11.5 x 4 cm. The attached peritoneum measures 12 x 10 by less than 0.1 cm and is unremarkable. The bladder measures 5.5 x 6 x 3 cm. The specimen is inked and the bladder is opened along the anterior urethra and bladder wall. There is an ulcerative mass 3.5 x 2.5 x 1.0 cm involving the right ureterovesical junction and extending to the trigone and posterior bladder neck which is 0.3 cm from the urethral margin. It is suspicious but not definitive for involving perivesical soft tissue. The right attached ureter measures 5 cm in length and is dilated to 1 cm in circumference. It appears to be directly involved by the tumor at the orifice. The remaining right ureteral mucosa is tan and smooth. The left attached ureter measures 3.5 cm in length and 0.5 cm in circumference and is unremarkable grossly. Serial sections through uninvolved bladder wall show it to be 1.1 cm in thickness. Located posterior to the bladder is a pear-shaped and symmetrical uterus measuring 7.2 x 5 x 2.8 cm overall with a smooth serosal surface. The exocervix measures 3 cm in diameter with a smooth mucosal surface. The specimen is opened laterally into anterior and posterior halves to show the endocervical canal to measure 2.2 cm in length by 0.2 to 0.8 cm in diameter with a tan glistening mucosal surface that is grossly normal. The endometrial cavity measures 3.2 x 0.9 cm and is slightly deviated to the left and is lined by a tan-brown shining endometrium which is 0.1 cm in greatest thickness. Serial sections of the myometrium show it to be 1.5 cm in thickness and to have multiple tan-white nodules present in the right lateral wall. These nodules range in size from 0.5 to 0.6 cm in diameter and show no hemorrhage or necrosis. The right and left ovaries are yellow and cerebriform and measure 2 x 0.8 x 0.6 cm and 1.8 x 0.8 x 0.8 cm, respectively. The right fallopian tube measures 6 cm in length and ranges from 0.2 to 0.4 cm in diameter, while the left fallopian tube measures 4 cm in length and ranges from 0.2 to 0.4 cm in diameter. Both fallopian tubes are tan-purple without gross lesions. Representative sections are submitted in 23 cassettes.

E: The specimen is received in formalin and labeled "R para caval lymph nodes". It consists of a segment of fibroadipose tissue measuring 4 x 1.5 x 0.3 cm containing multiple lymph nodes ranging in size from 0.2 to 1.3 cm in greatest dimension. The specimen is entirely submitted in two cassettes.

F: The specimen is received in formalin and labeled "R common iliac LN". It consists of multiple fragments of fibroadipose tissue measuring in aggregate 4 x 1.5 x 0.5 cm containing multiple lymph nodes ranging in size from 0.1 to 0.5 cm in greatest dimension. The specimen is entirely submitted in two cassettes.

Printed by:
Printed on:

Page 2 of 8
(Continued)

[page 3 of 8]
HX SURGICAL PATHOLOGY REPORT

* Final Report *

G: The specimen is received in formalin and labeled "Left para aortic LN". It consists of multiple fragments of fibroadipose tissue measuring in aggregate 2.5 x 1.5 x 0.5 cm containing multiple lymph nodes ranging in size from 0.5 to 1 cm in greatest dimension. The specimen is entirely submitted in two cassettes.

H: The specimen is received in formalin and labeled "L common iliac LN". It consists of multiple segments of fibroadipose tissue measuring in aggregate 4 x 2 x 0.5 cm containing multiple lymph nodes ranging in size from 0.6 to 2 cm in greatest dimension. The specimen is entirely submitted in three cassettes.

I: The specimen is received in formalin and labeled "R lymph node of cloquet". It consists of one lymph node with attached fat measuring 2 x 0.9 x 0.5 cm. This lymph node is trisected and entirely submitted in one cassette.

J: The specimen is received in formalin and labeled "R external iliac LN". It consists of two segments of fibroadipose tissue measuring in aggregate 3.5 x 1.5 x 0.5 cm containing four lymph nodes ranging from 0.7 to 1.8 cm in greatest dimension. The specimen is entirely submitted in two cassettes.

K: The specimen is received in formalin and labeled "R obturator / hypogastric LN". It consists of multiple segments of fibroadipose tissue measuring in aggregate 7 x 5 x 0.7 cm. Multiple lymph nodes are identified within the fatty tissue ranging in size from 0.5 to 1.5 cm in greatest dimension. The specimen is entirely submitted in eight cassettes.

L: The specimen is received in formalin and labeled "L lymph node of cloquet". It consists of a lymph node with attached fat measuring 2 cm in greatest dimension. The lymph node is bisected and entirely submitted in one cassette.

M: The specimen is received in formalin and labeled "L external iliac LN". It consists of a segment of adipose tissue measuring 3.5 x 1.1 x 0.4 cm containing three lymph nodes ranging from 0.5 to 1 cm in greatest dimension. The specimen is entirely submitted in one cassette.

N: The specimen is received in formalin and labeled "L obturator / hypogastric LN". It consists of multiple segments of fibroadipose tissue measuring in aggregate 7 x 4 x 1.5 cm. Multiple lymph nodes are identified within the fatty tissue ranging from 0.1 to 2 cm in greatest dimension. The specimen is entirely submitted in 10 cassettes.

O: The specimen is received in formalin and labeled "R pre sciatic LN". It consists of multiple segments of fibroadipose tissue measuring in aggregate 1.5 x 1 x 0.4 cm containing two lymph nodes measuring 0.4 to 1.2 cm in greatest dimension. The specimen is entirely submitted in one cassette.

P: The specimen is received in formalin and labeled "Pre sacral LN". It consists of a segment of fibroconnective tissue measuring 5 x 1.7 x 0.2 cm which is entirely submitted in two cassettes.

Q: The specimen is received in formalin and labeled "L pre sciatic LN". It consists of a fragment of fibroadipose

Printed by:
Printed on:

Page 3 of 8
(Continued)

[page 4 of 8]
HX SURGICAL PATHOLOGY REPORT

* Final Report *

tissue measuring 1 x 0.9 x 0.2 cm containing two possible lymph nodes ranging from 0.1 to 0.2 cm in greatest dimension. The specimen is entirely submitted in one cassette.

R: The specimen is received in formalin and labeled "L proximal ureter". It consists of a segment of ureter measuring 1.2 cm in length and 0.4 cm in diameter. There is a clip located at one end and centrally for a total of two clips. The side closest the clip is inked black and the specimen is serially sectioned and entirely submitted in one cassette.

S: The specimen is received in formalin and labeled "R proximal ureter". It consists of a segment of ureter measuring 1 cm in length and 0.6 cm in diameter. A clip is located centrally. The specimen is serially sectioned and entirely submitted in one cassette.

SECTIONS:

AFS: frozen section, right distal ureter all embedded
BFS: frozen section, left distal ureter all embedded
CFS: frozen section, apical urethral margin all embedded
D1: anterior bladder wall
D2: right lateral bladder wall
D3: right ureterovesical junction to urethra
D4: additional right attached ureter
D5-9: tumor to urethra
D10,11: representative sections tumor
D12: dome
D13: left ureterovesical junction
D14: left lateral bladder wall, above and below ureterovesical junction
D15: posterior bladder wall
D16: anterior cervix
D17: posterior cervix
D18: anterior endomyometrium
D19: posterior endomyometrium
D20: tan whorled nodules
D21: right ovary and right fallopian tube
D22: left ovary and left fallopian tube
D23: perivesical fat
E1,2: right paracaval lymph nodes all embedded
F1,2: right common iliac lymph node all embedded
G1,2: left para-aortic lymph node all embedded
H1-3: left common iliac lymph node all embedded
I: right lymph node of cloquet all embedded
J1,2: right external iliac lymph node all embedded
K1-8: right obturator/hypogastric lymph node all embedded

Printed by:
Printed on:

Page 4 of 8
(Continued)

[page 5 of 8]
HX SURGICAL PATHOLOGY REPORT

* Final Report *

L: left lymph node of cloquet all embedded
M: left external iliac lymph node - all embedded
N1-10: left obturator / hypogastric lymph node all embedded
O: right presciatic lymph node all embedded
P1,2: presacral lymph node all embedded
Q: left presciatic lymph node all embedded
R: left proximal ureter all embedded
S: right proximal ureter all embedded

INTRAOPERATIVE DIAGNOSIS:

FROZEN SECTION DIAGNOSIS:

AFS: Right distal ureter:

- no high-grade atypia or tumor identified

BFS: Left distal ureter:

- no high-grade atypia or tumor identified

CFS: Apical urethral margin:

- no high-grade atypia or tumor identified

DIAGNOSIS COMMENT:

Representative sections of invasive carcinoma are submitted for p53 assay by immunohistology, results of which will be issued in an addendum.

FINAL DIAGNOSIS:

RADICAL CYSTECTOMY, ANTERIOR EXENTERATION WITH CONTINENT URINARY DIVERSION AND GASTROSTOMY TUBE PLACEMENT:

RIGHT DISTAL URETER (A):

FROZEN SECTION DIAGNOSIS:

- NO HIGH GRADE ATYPIA OR TUMOR IDENTIFIED

FINAL DIAGNOSIS:

- BENIGN HYDROURETER
- NO UROTHELIAL DYSPLASIA OR MALIGNANCY IDENTIFIED

LEFT DISTAL URETER (B):

FROZEN SECTION DIAGNOSIS:

Printed by:

Printed on:

Page 5 of 8
(Continued)

[page 6 of 8]
HX SURGICAL PATHOLOGY REPORT

* Final Report *

- NO HIGH GRADE ATYPIA OR TUMOR IDENTIFIED

FINAL DIAGNOSIS:

- BENIGN URETER

- NO UROTHELIAL DYSPLASIA OR MALIGNANCY IDENTIFIED

APICAL URETHRAL MARGIN (C):

FROZEN SECTION DIAGNOSIS:

- NO HIGH GRADE ATYPIA OR TUMOR IDENTIFIED

FINAL DIAGNOSIS:

- BENIGN URETHRAL MUCOSA WITH ADJACENT ULCERATION, ASSOCIATED NECROSIS AND MULTINUCLEATED GIANT CELLS

- NO UROTHELIAL DYSPLASIA OR MALIGNANCY IDENTIFIED

BLADDER / UTERUS (D):

BLADDER:

- INVASIVE POORLY DIFFERENTIATED UROTHELIAL CARCINOMA WITH FOCAL SQUAMOID FEATURES (3.5 X 2.5 X 1.1 CM), GRADES 3 & 4/4, EXTENDING INTO DEEP MUSCULARIS PROPRIA WITHOUT INVOLVING PERIVESICAL SOFT TISSUE

- NO LYMPHOVASCULAR SPACE INVASION IDENTIFIED

- UROTHELIAL CARCINOMA IN SITU (FLAT LESION) INVOLVING MUCOSA ADJACENT TO INVASIVE CARCINOMA (RIGHT LATERAL WALL AND BLADDER NECK)

- RESECTION MARGINS, FREE OF UROTHELIAL DYSPLASIA AND MALIGNANCY

UTERUS:

- CERVIX, BENIGN SQUAMOUS AND ENDOCERVICAL MUCOSA EXHIBITING NO DYSPLASIA OR MALIGNANCY

- ENDOMETRIUM, ATROPHIC

- MYOMETRIUM, LEIOMYOMAS WITHOUT CELLULAR ATYPIA OR EVIDENCE MALIGNANCY

- BILATERAL FALLOPIAN TUBES AND OVARIES, BENIGN PHYSIOLOGIC CHANGES WITH NO ATYPICAL ELEMENTS OR MALIGNANCY IDENTIFIED

RIGHT PARACAVAL LYMPH NODES (E):

- NO MALIGNANCY IDENTIFIED IN NINE LYMPH NODES EXAMINED (0/9)

RIGHT COMMON ILIAC LYMPH NODES (F):

- NO MALIGNANCY IDENTIFIED IN 11 LYMPH NODES EXAMINED (0/11)

LEFT PARA AORTIC LYMPH NODES (G):

- NO MALIGNANCY IDENTIFIED IN SEVEN LYMPH NODES EXAMINED (0/7)

Printed by:

Printed on:

Page 6 of 8

(Continued)

[page 7 of 8]
HX SURGICAL PATHOLOGY REPORT

* Final Report *

LEFT COMMON ILIAC LYMPH NODES (H):

- NO MALIGNANCY IDENTIFIED IN SIX LYMPH NODES EXAMINED (0/6)

RIGHT LYMPH NODE OF CLOQUET (I):

- NO MALIGNANCY IDENTIFIED IN ONE LYMPH NODE EXAMINED (0/1)

RIGHT EXTERNAL ILIAC LYMPH NODES (J):

- NO MALIGNANCY IDENTIFIED IN FOUR LYMPH NODES EXAMINED (0/4)

RIGHT OBTURATOR / HYPOGASTRIC LYMPH NODES (K):

- NO MALIGNANCY IDENTIFIED IN 17 LYMPH NODES EXAMINED (0/17)

LEFT LYMPH NODE OF CLOQUET (L):

- NO MALIGNANCY IDENTIFIED IN ONE LYMPH NODE EXAMINED (0/1)

LEFT EXTERNAL ILIAC LYMPH NODES (M):

- NO MALIGNANCY IDENTIFIED IN FOUR LYMPH NODES EXAMINED (0/4)

LEFT OBTURATOR / HYPOGASTRIC LYMPH NODES (N):

- NO MALIGNANCY IDENTIFIED IN 11 LYMPH NODES EXAMINED (0/11)

RIGHT PRESACRAL LYMPH NODES (O):

- NO MALIGNANCY IDENTIFIED IN THREE LYMPH NODES EXAMINED (0/3)

PRESACRAL LYMPH NODES (P):

- NO LYMPH NODES OR MALIGNANCY IDENTIFIED (0/0) [TOTALLY EMBEDDED]

LEFT PRESACRAL LYMPH NODES (Q):

- NO MALIGNANCY IDENTIFIED IN TWO LYMPH NODES EXAMINED (0/2)

LEFT PROXIMAL URETER (R):

- BENIGN URETER
- NO UROTHELIAL DYSPLASIA OR MALIGNANCY IDENTIFIED

RIGHT PROXIMAL URETER (S):

- BENIGN HYDROURETER
- NO UROTHELIAL DYSPLASIA OR MALIGNANCY IDENTIFIED

PATHOLOGIC TNM STAGE: pTis,T2bN0MX

Printed by:

Printed on:

Page 7 of 8
(Continued)

[page 8 of 8]
HX SURGICAL PATHOLOGY REPORT

* Final Report *

Completed Action List:

Printed by:
Printed on:

Page 8 of 8
(End of Report)

Source: NCI Genomic Data Commons file 85fc4c47-4b1f-4385-b7bf-4efc7c533157 (TCGA-XF-AAME.F59EB865-9B98-4A22-9237-513CADD28F65.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).